CGCI case BLGSP-71-23-00468 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8678aea1-0441-49f8-8071-c47c46c2d568

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Dead; Days to death: 142 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 45.5 years (16,614 days); Year of diagnosis: 2010; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 142 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Other; Sites of involvement: Small intestine / Stomach / Bone marrow / Mouth.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Axillary; Lymph nodes tested: 1; Tumor largest dimension diameter: 4 cm.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 142 days; Disease response: With Tumor.
- Follow-up contacts recording only the day: day -83, day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 2467 [Blood test normal range upper: 480].

Other clinical attributes
- Day -83: Comorbidities: HIV/AIDS.
- Day -83: Risk factors: HIV/AIDS.
- Day 0: Weight: 56 kg; Height: 168.5 cm; BMI: 19.7.
- Day 0: Risk factors: Helicobacter pylori-Associated Gastritis.
- Day 0: Comorbidities: Helicobacter pylori Infection.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00468-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00468-01A-01-S1-HE: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-23-00468-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-23-00468-14A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00468-14A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 40.
  Slide BLGSP-71-23-00468-14A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 30.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease, History relevant infectious diseases: History relevant infectious diagnosis: Helicobacter pylori.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 3; Extranodal involvment other: Bone marrow and palate; Days from index date to tumor sample procurement: -6; Lymph nodes examined: Yes; Other pos node location: left axillary; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 2467; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD3.
